Gene-level copy-number profile of tumor specimen TCGA-YD-A9TB-06A from TCGA case TCGA-YD-A9TB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-YD-A9TB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.a0d56b2e-7c63-4e20-b876-5ee05059ab74.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YD-A9TB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3fdb008c-223d-48d1-87d2-e5073e6356ea

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 1: 24,601; copy number 2: 19,026; copy number 3: 9,023; copy number 4: 4,455; copy number 5: 2,018; copy number 6: 692.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YD-A9TB-06A-12D-A400-01): tumor purity 0.6, ploidy 3.98, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 13,767 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 3 (broad region; genes not listed).
- chr4:49,096–190,092,279, 2,655 genes, copy number 3–4 (broad region; genes not listed).
- chr6:167,607–65,707,226, 1,564 genes, copy number 4–5 (within-gene range 2–5) (broad region; genes not listed).
- chr6:66,710,242–66,728,904, 2 genes, copy number 3: AL450336.1, RNU7-66P.
- chr7:70,972–159,233,377, 3,014 genes, copy number 3–5 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 3–5 (broad region; genes not listed).
- chr14:22,132,553–22,513,998, 64 genes, copy number 3 (broad region; genes not listed).
- chr16:11,555–2,899,382, 270 genes, copy number 3 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 3 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 3–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,601. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
